Gene-level copy-number profile of tumor specimen TCGA-94-A5I4-01A from TCGA case TCGA-94-A5I4, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Main bronchus; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.1 years (22,299 days).
Specimen TCGA-94-A5I4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f4d38eab-08cc-4a45-962a-3502903e14b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-A5I4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/064e3b65-c929-4e21-be5c-f09f22eff198

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 657; copy number 2: 28,277; copy number 3: 12,404; copy number 4: 9,240; copy number 5: 3,980; copy number 6: 2,550; copy number 7: 1,715; copy number 8: 299; copy number 9: 35; copy number 10: 611; copy number 11: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-A5I4-01A-11D-A26L-01): tumor purity 0.59, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:157,162,663–158,088,997, 12 genes (within-gene range 0–8): KRT18P34, AC104411.1, RNA5SP146, AC092944.1, AC092944.2, AC092944.3, VEPH1, PTX3, SLC66A1L, AC084212.1, AC079943.2, RN7SKP46.
- chr18:77,970,637–78,140,887, 4 genes (within-gene range 0–2): LINC01029, AC134978.1, RNU6-655P, AC107892.1.
- chr18:78,908,629–79,378,287, 13 genes: AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2.
- chr18:79,420,836–79,422,780, 1 gene: AC018445.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,206 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,674,857–208,854,503, 1,918 genes, copy number 5–7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:211,104,934–211,299,189, 2 genes, copy number 8: AC012491.1, RPS27P10.
- chr2:215,611,563–223,602,361, 196 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr3:157,976,561–198,222,513, 709 genes, copy number 8–10 (broad region; genes not listed).
- chr4:76,886,029–81,334,418, 59 genes, copy number 6: AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5, MICOS10P4, ANXA3, Y_RNA, LINC01094, HIGD1AP13, AC112253.1, AC098818.1, AC098818.2, BMP2K, AC098818.3, PAQR3, RN7SL127P, LINC01088, NAA11, GK2, LINC00989, OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2, KPNA2P1, RPSAP39, AC021127.1, PRDM8, FGF5, CFAP299, AC105917.1, BMP3, PRKG2, PRKG2-AS1, RNU5A-2P.
- chr4:90,838,903–91,325,306, 3 genes, copy number 5: TMSB4XP8, AC004054.1, AC074124.1.
- chr6:60,281,444–73,828,316, 138 genes, copy number 5–11 (broad region; genes not listed).
- chr7:20,134,655–20,217,404, 1 gene, copy number 6 (within-gene range 2–6): MACC1.
- chr7:20,217,577–21,221,428, 16 genes, copy number 6: AC005083.1, AC099342.1, AC004130.2, ITGB8, AC004130.1, EEF1A1P27, AC002486.2, ABCB5, AC002486.1, SP8, RPL23P8, LINC01162, RPS26P30, AC080068.1, RN7SL542P, ASS1P11.
- chr7:25,593,304–37,449,249, 249 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr7:81,946,444–149,624,752, 1,285 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr8:34,784,028–35,093,509, 3 genes, copy number 5: LINC01288, AC087343.1, AC099685.1.
- chr8:36,378,069–38,468,834, 59 genes, copy number 7 (within-gene range 2–7): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22.
- chr8:38,901,235–60,516,795, 328 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:62,110,524–140,638,283, 1,098 genes, copy number 5 (broad region; genes not listed).
- chr8:140,732,564–140,732,653, 1 gene, copy number 5: MIR151A.
- chr9:60,914,407–102,657,514, 743 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:104,328,320–119,524,125, 226 genes, copy number 5–6 (broad region; genes not listed).
- chr9:120,600,811–138,203,325, 557 genes, copy number 5–7 (broad region; genes not listed).
- chr10:5,004,710–5,135,226, 4 genes, copy number 7 (within-gene range 4–7): U8, AKR1C3, U8, AKR1C5P.
- chr10:42,149,310–44,515,421, 72 genes, copy number 6 (broad region; genes not listed).
- chr12:66,767–7,900,140, 253 genes, copy number 6 (broad region; genes not listed).
- chr12:8,533,305–34,249,958, 553 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr12:61,600,067–61,600,843, 1 gene, copy number 6: DUX4L52.
- chr18:47,390–15,330,282, 376 genes, copy number 6 (broad region; genes not listed).
- chr19:31,149,979–39,476,670, 356 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
